Somatic mutation profile of tumor specimen MP2PRT-PAVEKF-TMP1-A (aliquot MP2PRT-PAVEKF-TMP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVEKF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,572 days).
Specimen MP2PRT-PAVEKF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f89dea4-ef5b-42cc-a2c7-1bcc633caaa6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVEKF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVEKF-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4e05413-982a-4358-b4d3-f7284cea0367

The open-access MAF lists 107 somatic variants for this specimen: 75 protein-altering or splice-affecting, 26 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 26, Nonsense Mutation 5, RNA 3, Translation Start Site 1, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.1799G>C p.R600T | Missense Mutation (SNP) | VAF 179/366 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.673); catalogued as COSV53175813; called by muse, mutect2, varscan2
- ANKRD30A | c.1711C>G p.L571V (on ENST00000611781; = p.L515V on NM_052997.2) | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.067); catalogued as rs751403983, COSV100654603; called by muse, mutect2
- ANKRD30A | c.2425C>G p.L809V (on ENST00000611781; = p.L753V on NM_052997.2) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1427866844; called by muse, mutect2, varscan2
- ARHGEF17 | c.824C>A p.S275* | Nonsense Mutation (SNP) | VAF 239/520 reads (46%) | catalogued as COSV99735376; called by muse, mutect2, varscan2
- C12orf60 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 153/339 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs559396395; called by muse, mutect2, varscan2
- CRACDL | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 254/566 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as rs935545816; called by muse, mutect2, varscan2
- DBI | c.235G>A p.E79K (on ENST00000355857 / NM_001079862.3; = p.E96K on NM_020548.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 123/224 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as rs776066590; called by muse, mutect2, varscan2
- DCC | c.3533C>G p.S1178C | Missense Mutation (SNP) | VAF 152/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766330170; called by muse, mutect2, varscan2
- DLGAP2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 388/827 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs1191224744, COSV101422045; called by muse, mutect2, varscan2
- EOMES | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 246/549 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.41); catalogued as rs1289160707, COSV55415054, COSV55415985; called by muse, mutect2, varscan2
- FGF13 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 150/321 reads (47%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.099); catalogued as rs867886693, COSV65446326; called by muse, mutect2, varscan2
- FGFR2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 128/426 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.423); catalogued as COSV60653130; called by muse, mutect2, varscan2
- FREM2 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 201/420 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV99747402; called by muse, mutect2, varscan2
- FZD3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1336630473; called by muse, mutect2, varscan2
- GJA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs781915687, COSV53788224; called by muse, mutect2, varscan2
- LRTM1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 25/462 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs773408157, COSV99836070; called by muse, mutect2
- MACC1 | c.467G>A p.S156N | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs769782644; called by muse, mutect2, varscan2
- MRTFB | c.2426C>G p.S809* (on ENST00000571589 / NM_001365412.2; = p.S759* on NM_014048.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 99/404 reads (25%) | catalogued as rs1240270539; called by muse, mutect2, varscan2
- NOCT | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 132/296 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as COSV99763934; called by muse, mutect2, varscan2
- NSUN3 | c.1001C>G p.S334* | Nonsense Mutation (SNP) | VAF 109/214 reads (51%) | catalogued as COSV100113148; called by muse, mutect2, varscan2
- PCDH11X | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 211/420 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143617694, COSV53511180; called by muse, mutect2, varscan2
- PIGA | c.803G>A p.R268K | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as COSV61236820; called by muse, mutect2, varscan2
- PLOD1 | c.750G>C p.L250F | Missense Mutation (SNP) | VAF 158/327 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV99538717; called by muse, mutect2, varscan2
- POU2AF1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 212/452 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV67577090; called by muse, mutect2, varscan2
- SCML2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 117/255 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV52619854; called by muse, mutect2, varscan2
- SEMA3A | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV54870818; called by muse, mutect2, varscan2
- SLITRK3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 91/183 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as rs763413669; called by muse, mutect2, varscan2
- TRIM55 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 25/434 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs754147349, COSV52545616; called by muse, mutect2
- USP39 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 16/420 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1485348665, COSV60382746; called by muse, mutect2
- ZBBX | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 110/244 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as rs747465475, COSV56793806; called by muse, mutect2
- ZRANB1 | c.943C>G p.L315V | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62843606; called by muse, mutect2, varscan2
- ADCY10 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 173/318 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AJM1 | c.765C>G p.D255E | Missense Mutation (SNP) | VAF 358/659 reads (54%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.478); called by muse, mutect2
- ATP5F1A | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 119/240 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AVL9 | c.1581G>C p.K527N | Missense Mutation (SNP) | VAF 104/220 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- BNIP3L | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 153/327 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- C1orf94 | c.1427C>G p.S476C (on ENST00000488417 / NM_001134734.2; = p.S286C on NM_032884.5) | Missense Mutation (SNP) | VAF 134/303 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CC2D1A | c.833G>C p.G278A | Missense Mutation (SNP) | VAF 198/402 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- CCDC178 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 54/113 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CCNL1 | c.1363G>C p.D455H | Missense Mutation (SNP) | VAF 122/274 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CDC42EP1 | c.571G>C p.D191H | Missense Mutation (SNP) | VAF 253/541 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CENPI | c.1769C>A p.S590Y | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- EVX2 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 155/447 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- FAM3C | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 85/208 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.012); called by muse, varscan2
- FAT1 | c.8855G>C p.R2952T | Missense Mutation (SNP) | VAF 90/248 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- GALNT3 | c.1480C>G p.P494A | Missense Mutation (SNP) | VAF 90/181 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GGN | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 314/621 reads (51%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.074); called by muse, varscan2
- GPR180 | c.1234C>G p.H412D | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- H2BC9 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 130/301 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- IBTK | c.2334G>C p.K778N | Missense Mutation (SNP) | VAF 132/240 reads (55%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IKZF1 | c.730dup p.T244Nfs*2 | Frame Shift Ins (INS) | VAF 102/298 reads (34%) | called by mutect2, pindel, varscan2
- KIF21A | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 99/229 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- NEK10 | c.1792G>C p.D598H | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- NEK5 | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- NLRC4 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 132/240 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIK3CB | c.2171G>A p.S724N | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCL1 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 166/346 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PLXND1 | c.4547T>C p.L1516P | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PNISR | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 111/273 reads (41%) | called by muse, mutect2, varscan2
- POLK | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PPP4R4 | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- PRSS36 | c.1413G>T p.W471C | Missense Mutation (SNP) | VAF 26/956 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- SHROOM4 | c.2137G>C p.E713Q | Missense Mutation (SNP) | VAF 312/614 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TBC1D12 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- TCERG1L | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIO | c.3393G>C p.K1131N | Missense Mutation (SNP) | VAF 122/267 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TSHZ3 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 198/426 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- USP6 | c.3962C>G p.S1321* | Nonsense Mutation (SNP) | VAF 84/185 reads (45%) | called by muse, mutect2, varscan2
- WDR89 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- XKR5 | c.1614G>C p.Q538H | Missense Mutation (SNP) | VAF 187/380 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZNF280C | c.2053C>G p.L685V | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZNF665 | c.271C>G p.Q91E (on ENST00000600412; = p.Q156E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/331 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF888 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.968); called by muse, varscan2
- ZNF888 | c.412C>A p.Q138K | Missense Mutation (SNP) | VAF 67/272 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.711); called by muse, varscan2
- ZSWIM4 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 242/550 reads (44%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- AC134980.2 | c.882G>T p.V294= | Silent (SNP) | VAF 37/90 reads (41%) | catalogued as COSV60909080; called by muse, mutect2, varscan2
- AKAP8L | c.1504C>T p.L502= | Silent (SNP) | VAF 126/243 reads (52%) | called by muse, mutect2, varscan2
- BPIFB4 | c.865C>A p.R289= | Silent (SNP) | VAF 160/355 reads (45%) | catalogued as COSV64951433; called by muse, mutect2, varscan2
- CFAP58 | c.367C>T p.L123= | Silent (SNP) | VAF 170/364 reads (47%) | called by muse, mutect2, varscan2
- CNGA3 | c.1884G>A p.E628= | Silent (SNP) | VAF 167/444 reads (38%) | called by muse, mutect2, varscan2
- CRACDL | c.2025G>A p.P675= | Silent (SNP) | VAF 257/497 reads (52%) | catalogued as COSV67408190, COSV67410071; called by muse, mutect2, varscan2
- CRISPLD2 | c.1242G>A p.P414= | Silent (SNP) | VAF 131/414 reads (32%) | catalogued as rs371283010; called by muse, mutect2, varscan2
- DNAH11 | c.12132C>A p.I4044= | Silent (SNP) | VAF 180/348 reads (52%) | catalogued as rs1375468559; called by muse, mutect2, varscan2
- EIF4A3 | c.363G>A p.Q121= | Silent (SNP) | VAF 103/215 reads (48%) | catalogued as rs755408251; called by muse, mutect2, varscan2
- ERCC4 | c.2742G>T p.G914= | Silent (SNP) | VAF 159/636 reads (25%) | called by muse, mutect2, varscan2
- KCND2 | c.135G>A p.L45= | Silent (SNP) | VAF 17/539 reads (3%) | catalogued as COSV58574313, COSV58575553, COSV58583469; called by muse, mutect2
- MORC4 | c.2775C>T p.I925= | Silent (SNP) | VAF 178/380 reads (47%) | called by muse, mutect2, varscan2
- NRG3 | c.249C>T p.L83= | Silent (SNP) | VAF 190/405 reads (47%) | called by muse, mutect2, varscan2
- NSMF | c.240G>A p.E80= | Silent (SNP) | VAF 218/554 reads (39%) | catalogued as rs976864259; called by muse, mutect2, varscan2
- NUP205 | c.2460C>T p.L820= | Silent (SNP) | VAF 131/380 reads (34%) | catalogued as COSV53659284; called by muse, mutect2, varscan2
- PCDH19 | c.1998C>T p.L666= | Silent (SNP) | VAF 228/443 reads (51%) | catalogued as COSV55259272; called by muse, mutect2, varscan2
- POLQ | c.1116G>T p.V372= | Silent (SNP) | VAF 89/200 reads (45%) | called by muse, mutect2, varscan2
- RNFT1 | c.1233C>T p.L411= | Silent (SNP) | VAF 74/239 reads (31%) | called by muse, mutect2, varscan2
- SEC14L4 | c.1220G>A p.*407= | Silent (SNP) | VAF 115/239 reads (48%) | called by muse, mutect2, varscan2
- SEPTIN7 | c.9C>T p.V3= | Silent (SNP) | VAF 179/377 reads (47%) | catalogued as rs1223594914; called by muse, mutect2, varscan2
- SH2D4B | c.81C>T p.L27= | Silent (SNP) | VAF 152/353 reads (43%) | called by muse, mutect2, varscan2
- TARBP2 | c.276C>G p.L92= (on ENST00000266987 / NM_134323.2; = p.L71= on NM_004178.4) | Silent (SNP) | VAF 135/333 reads (41%) | called by muse, varscan2
- TFAP2A | c.636C>A p.V212= (on ENST00000482890; = p.V204= on NM_001032280.3) | Silent (SNP) | VAF 260/468 reads (56%) | catalogued as COSV60230773; called by muse, varscan2
- UGT2B11 | c.270C>T p.I90= | Silent (SNP) | VAF 76/188 reads (40%) | called by muse, mutect2, varscan2
- UTP14A | c.189G>A p.E63= | Silent (SNP) | VAF 106/251 reads (42%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.1485C>T p.L495= | Silent (SNP) | VAF 58/255 reads (23%) | called by muse, mutect2, varscan2
- ARHGAP42 | c.*237T>G | 3'UTR (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- IGHV3-53 | chr14:106592675 ins CCTCCAAA | 3'Flank (INS) | VAF 20/34 reads (59%) | called by pindel, varscan2
- NPAP1L | n.967G>T | RNA (SNP) | VAF 111/409 reads (27%) | called by muse, mutect2, varscan2
- NPAP1L | n.609G>A | RNA (SNP) | VAF 134/454 reads (30%) | called by muse, varscan2
- NPAP1L | n.3G>A | RNA (SNP) | VAF 79/243 reads (33%) | called by muse, mutect2, varscan2
- ZNF665 | c.-47C>A | 5'UTR (SNP) | VAF 59/157 reads (38%) | called by muse, mutect2, varscan2
